Somatic mutation profile of tumor specimen C3N-04276-01 (aliquot CPT0245350012) from CPTAC case C3N-04276, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 68.1 years (24,876 days).
Specimen C3N-04276-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63776584-427b-42af-a4f9-1aa6d45d7523.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04276-31 (Blood Derived Normal), aliquot CPT0245390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6801e36-bc9a-4a6c-b794-fbd7a7554516

The open-access MAF lists 208 somatic variants for this specimen: 135 protein-altering or splice-affecting, 48 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 48, Intron 15, Nonsense Mutation 8, 5'UTR 5, Frame Shift Del 4, Frame Shift Ins 3, RNA 3, Splice Site 2, Splice Region 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.4934G>A p.R1645Q (on ENST00000303395 / NM_001202435.3; = p.R1634Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121917976, CM072001, CM1511233, COSV57662283; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 487/704 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSM2A | c.1509+3G>A | Splice Region (SNP) | VAF 92/264 reads (35%) | catalogued as rs1417873360; called by muse, mutect2, varscan2
- AMER1 | c.706G>T p.G236W | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV57662814; called by muse, mutect2, varscan2
- AMOTL1 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.014); catalogued as rs779577913; called by muse, mutect2, varscan2
- APBA1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV55231083; called by muse, mutect2, varscan2
- ASTN1 | c.2628G>T p.Q876H | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56069802, COSV99920086; called by muse, mutect2, varscan2
- CD93 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1248609729, COSV55667078; called by muse, mutect2, varscan2
- CDKN2A | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 226/399 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1201199303; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP43 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs771419279, COSV53381065; called by muse, mutect2, varscan2
- CPXM2 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs776692250; called by mutect2, varscan2
- CRAMP1 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.473); catalogued as rs1219238128; called by muse, mutect2, varscan2
- CREBBP | c.4471C>A p.Q1491K | Missense Mutation (SNP) | VAF 186/558 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs201156486, COSV52120333, COSV52125130; called by muse, mutect2, varscan2
- CSMD3 | c.5048C>A p.S1683Y (on ENST00000297405 / NM_001363185.1; = p.S1579Y on NM_052900.3) | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV52119423, COSV99828086; called by muse, mutect2, varscan2
- CTNNA2 | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 296/750 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV100784253, COSV63568291; called by muse, mutect2, varscan2
- DENND1A | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 93/310 reads (30%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs770939915; called by muse, mutect2, varscan2
- FSCB | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV61219704; called by muse, varscan2
- FYB1 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 127/394 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs757419118; called by muse, mutect2, varscan2
- GABRA6 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 187/618 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757447117, COSV50879377; called by muse, mutect2, varscan2
- GPATCH1 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 39/144 reads (27%) | catalogued as COSV50133197; called by muse, mutect2, varscan2
- GRID2 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 111/324 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs538076349; called by muse, mutect2, varscan2
- HNRNPU | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 259/1039 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.864); catalogued as rs773969888; called by muse, mutect2, varscan2
- IQGAP2 | c.3881T>C p.I1294T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1356876846; called by muse, mutect2, varscan2
- L1CAM | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 138/188 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs1557091785, COSV62827843, COSV62828577; called by muse, mutect2, varscan2
- LDHAL6B | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 86/259 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55683323, COSV55683419; called by muse, mutect2, varscan2
- MTPAP | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 158/572 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.43); catalogued as COSV53931631; called by muse, mutect2, varscan2
- MUC22 | c.895A>C p.T299P | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0.04); catalogued as rs896871447, COSV73736406; called by mutect2, varscan2
- MUC4 | c.4352C>T p.T1451I | Missense Mutation (SNP) | VAF 111/280 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.517); catalogued as rs779944667; called by muse, mutect2, varscan2
- MYL1 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58974035; called by muse, mutect2, varscan2
- OGDHL | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs774306809, COSV65105065; called by muse, mutect2, varscan2
- OPRPN | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.068); catalogued as COSV68192747; called by muse, mutect2, varscan2
- OR11H1 | c.493G>T p.V165F | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV99421792; called by mutect2, varscan2
- OSBPL6 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51919092; called by muse, mutect2, varscan2
- PEPD | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 168/454 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.447); catalogued as rs751121493; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGR | c.1319C>A p.T440K | Missense Mutation (SNP) | VAF 134/370 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.075); catalogued as COSV54813741; called by muse, mutect2, varscan2
- PLEC | c.13627G>A p.V4543M (on ENST00000322810 / NM_201380.4; = p.V4433M on NM_000445.5) | Missense Mutation (SNP) | VAF 186/505 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs782059675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.3461G>A p.R1154Q (on ENST00000322810 / NM_201380.4; = p.R1044Q on NM_000445.5) | Missense Mutation (SNP) | VAF 134/438 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs782374414; called by muse, mutect2, varscan2
- POLR2A | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs565133398; called by muse, mutect2, varscan2
- PPP1R9A | c.126A>T p.E42D | Missense Mutation (SNP) | VAF 138/307 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99196756; called by muse, mutect2, varscan2
- RANBP17 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs764213241, COSV101206389; called by muse, mutect2, varscan2
- RAP1GDS1 | c.354C>G p.Y118* (on ENST00000408927 / NM_001100427.2; = p.Y119* on NM_021159.5) | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | catalogued as COSV52786179, COSV52786432; called by muse, mutect2, varscan2
- RASGRF1 | c.2689C>A p.R897S | Missense Mutation (SNP) | VAF 125/414 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67249948; called by muse, mutect2, varscan2
- RGS18 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201015118; called by muse, mutect2, varscan2
- RYR2 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200685968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL1 | c.3829G>T p.G1277W | Missense Mutation (SNP) | VAF 120/319 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551229718; called by muse, mutect2, varscan2
- SLC11A1 | c.1274C>A p.S425* | Nonsense Mutation (SNP) | VAF 42/120 reads (35%) | catalogued as COSV51917173; called by muse, mutect2, varscan2
- SLC12A1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs1442023118; called by muse, mutect2, varscan2
- SLC14A2 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs148968678; called by muse, mutect2, varscan2
- SLC38A4 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs760817445, COSV56966129; called by muse, mutect2, varscan2
- SLC45A4 | c.1333G>T p.A445S (on ENST00000517878 / NM_001286646.2; = p.A394S on NM_001080431.2) | Missense Mutation (SNP) | VAF 119/714 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.554); catalogued as rs748850244; called by muse, mutect2, varscan2
- SLC6A19 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 119/344 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs961526802, COSV57249361; called by muse, mutect2, varscan2
- TAS2R9 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.184); catalogued as rs779488054; called by muse, mutect2, varscan2
- TGM6 | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 188/579 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as rs1308782514; called by muse, mutect2, varscan2
- TMEM200C | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.243); catalogued as rs1318789352; called by muse, mutect2, varscan2
- TPH1 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200405204; called by muse, mutect2, varscan2
- UAP1L1 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV64306124; called by muse, mutect2, varscan2
- ZNF44 | c.818A>G p.Y273C (on ENST00000356109 / NM_001164276.2; = p.Y225C on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/322 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs767885528; called by muse, mutect2, varscan2
- ZNF780B | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 82/276 reads (30%) | catalogued as rs761498452, COSV55462893; called by muse, mutect2, varscan2
- ZNF791 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.21); catalogued as rs747479365; called by muse, varscan2
- ZNF804A | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs142766490, COSV56444477; called by muse, mutect2, varscan2
- AAK1 | c.2665G>T p.A889S | Missense Mutation (SNP) | VAF 167/452 reads (37%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ACCSL | c.268C>A p.L90M | Missense Mutation (SNP) | VAF 100/253 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADGRB1 | c.4127G>T p.R1376L | Missense Mutation (SNP) | VAF 139/426 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADK | c.140+4_140+7dup | Frame Shift Ins (INS) | VAF 42/175 reads (24%) | called by mutect2, varscan2
- ADPRM | c.237T>A p.Y79* | Nonsense Mutation (SNP) | VAF 33/130 reads (25%) | called by muse, mutect2, varscan2
- AFF4 | c.2133del p.R711Sfs*6 | Frame Shift Del (DEL) | VAF 85/271 reads (31%) | called by mutect2, pindel, varscan2
- AGAP9 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 225/1556 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AJUBA | c.419del p.G140Afs*102 | Frame Shift Del (DEL) | VAF 89/209 reads (43%) | called by mutect2, pindel, varscan2
- ALMS1 | c.4910T>G p.L1637R | Missense Mutation (SNP) | VAF 128/312 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- APBA2 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 239/722 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.346); called by mutect2, varscan2
- ARHGEF11 | c.935A>T p.Q312L | Missense Mutation (SNP) | VAF 172/351 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP5PD | c.220-6T>A | Splice Region (SNP) | VAF 72/238 reads (30%) | called by muse, mutect2, varscan2
- BABAM2 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 130/248 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CATSPERG | c.2476-1G>T p.X826_splice | Splice Site (SNP) | VAF 50/153 reads (33%) | called by muse, mutect2, varscan2
- CDX1 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP47 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 48/69 reads (70%) | called by muse, mutect2, varscan2
- CFAP58 | c.2351T>G p.L784R | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP61 | c.1935G>T p.M645I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- CNTN4 | c.2593A>G p.T865A | Missense Mutation (SNP) | VAF 103/205 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- CNTNAP5 | c.2930A>G p.H977R | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- COBLL1 | c.1448C>T p.S483L (on ENST00000392717; = p.S445L on NM_014900.5) | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSPG4 | c.2888_2911del p.E963_L970del | In Frame Del (DEL) | VAF 51/222 reads (23%) | called by mutect2, pindel*
- CYLC2 | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CYP17A1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- DOCK1 | c.4342A>G p.K1448E | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- DOCK7 | c.3731C>T p.P1244L (on ENST00000635253 / NM_001367561.1; = p.P1213L on NM_033407.3) | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- DYRK4 | c.500T>A p.V167E | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM135A | c.1952C>G p.S651C (on ENST00000370479 / NM_001351599.1; = p.S438C on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- FAT1 | c.2079dup p.H694Tfs*24 | Frame Shift Ins (INS) | VAF 66/194 reads (34%) | called by mutect2, pindel, varscan2
- FAT4 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.994); called by muse, mutect2
- FIBCD1 | c.672A>T p.R224S | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- FMN2 | c.3664G>T p.A1222S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- FOXP4 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- FZD9 | c.191C>A p.T64K | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- GIGYF1 | c.1121C>A p.T374N | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GPR173 | c.223T>A p.C75S | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN1 | c.5459T>A p.V1820E | Missense Mutation (SNP) | VAF 163/342 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- JAKMIP3 | c.2015A>T p.E672V | Missense Mutation (SNP) | VAF 98/344 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- KCNN2 | c.861C>A p.S287R (on ENST00000264773; = p.S499R on NM_021614.4) | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRN3 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MDN1 | c.4808G>C p.R1603T | Missense Mutation (SNP) | VAF 90/314 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MPHOSPH10 | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 74/357 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRS2 | c.407G>C p.R136T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- NBAS | c.1238_1247del p.S413* | Frame Shift Del (DEL) | VAF 159/367 reads (43%) | called by mutect2, pindel, varscan2
- NRG3 | c.1820A>G p.E607G (on ENST00000404547 / NM_001370084.1; = p.E583G on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 139/435 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- OLFM3 | c.6G>T p.Q2H | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OR6F1 | c.826G>T p.V276F | Missense Mutation (SNP) | VAF 87/460 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PCDH11X | c.2836C>A p.P946T | Missense Mutation (SNP) | VAF 168/281 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PDE1A | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PLCB3 | c.3437G>T p.R1146L | Missense Mutation (SNP) | VAF 112/390 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POTEG | c.353del p.G118Afs*49 | Frame Shift Del (DEL) | VAF 190/1592 reads (12%) | called by mutect2, varscan2
- PPFIA2 | c.3323G>T p.W1108L | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RNF125 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ROR1 | c.2508C>G p.Y836* | Nonsense Mutation (SNP) | VAF 134/417 reads (32%) | called by muse, mutect2, varscan2
- SI | c.2228C>A p.T743N | Missense Mutation (SNP) | VAF 176/377 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SLC30A8 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 143/812 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SNRPN | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SRP68 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 95/245 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- TBC1D17 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TCHH | c.3148T>C p.Y1050H | Missense Mutation (SNP) | VAF 126/585 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- TKT | c.1049T>A p.I350N | Missense Mutation (SNP) | VAF 127/229 reads (55%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- TLL1 | c.1262-1G>C p.X421_splice | Splice Site (SNP) | VAF 59/226 reads (26%) | called by muse, mutect2, varscan2
- TMEM67 | c.296dup p.C100Vfs*20 | Frame Shift Ins (INS) | VAF 49/176 reads (28%) | called by mutect2, pindel, varscan2
- TNN | c.1190C>A p.T397N | Missense Mutation (SNP) | VAF 100/188 reads (53%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TNRC18 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- TTLL11 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 78/293 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); called by muse, varscan2
- TTN | c.102871T>C p.C34291R (on ENST00000591111; = p.C26867R on NM_003319.4) | Missense Mutation (SNP) | VAF 71/179 reads (40%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- UACA | c.2888T>G p.L963R | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ULK1 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 174/383 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- USP24 | c.7760G>T p.S2587I | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- WDR76 | c.396G>C p.M132I | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF551 | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 98/347 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- ZNF578 | c.1252C>G p.H418D | Missense Mutation (SNP) | VAF 109/350 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF669 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- ZNF91 | c.2306C>G p.P769R | Missense Mutation (SNP) | VAF 100/332 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA6 | c.774C>A p.L258= | Silent (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- ADCY8 | c.60G>A p.P20= | Silent (SNP) | VAF 67/286 reads (23%) | called by muse, mutect2, varscan2
- ADGRA2 | c.3300C>T p.P1100= | Silent (SNP) | VAF 73/234 reads (31%) | catalogued as rs1445283550; called by muse, mutect2, varscan2
- ASXL2 | c.3666C>A p.T1222= | Silent (SNP) | VAF 165/356 reads (46%) | called by muse, mutect2, varscan2
- BAZ1A | c.711A>G p.G237= | Silent (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
- BTBD8 | c.1452G>A p.T484= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1306864273; called by muse, mutect2
- CALN1 | c.447G>C p.T149= (on ENST00000329008 / NM_001017440.3; = p.T191= on NM_031468.4) | Silent (SNP) | VAF 76/172 reads (44%) | catalogued as COSV61119273; called by muse, mutect2, varscan2
- CDC73 | c.165C>T p.Y55= | Silent (SNP) | VAF 83/400 reads (21%) | catalogued as CM023088, CM109298, COSV66466961, COSV66470214; called by muse, mutect2, varscan2
- CEP128 | c.1339C>T p.L447= | Silent (SNP) | VAF 145/281 reads (52%) | called by muse, mutect2, varscan2
- FAM184B | c.1815G>A p.L605= | Silent (SNP) | VAF 67/178 reads (38%) | catalogued as rs766552472; called by muse, mutect2, varscan2
- FAT4 | c.10284C>A p.V3428= | Silent (SNP) | VAF 60/191 reads (31%) | called by muse, mutect2, varscan2
- FLT3 | c.1668C>T p.V556= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as rs777127892, COSV54058658; called by muse, mutect2, varscan2
- FMN2 | c.3309C>T p.P1103= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs761685189, COSV60415143; called by muse, varscan2
- GUCY2C | c.1629C>T p.N543= | Silent (SNP) | VAF 45/164 reads (27%) | catalogued as rs756436056; called by muse, mutect2, varscan2
- HAUS5 | c.1611C>T p.L537= | Silent (SNP) | VAF 55/239 reads (23%) | catalogued as rs746696536; called by muse, mutect2, varscan2
- HECW2 | c.2943G>C p.A981= | Silent (SNP) | VAF 59/218 reads (27%) | catalogued as rs748423196; called by muse, mutect2, varscan2
- KRT6B | c.472C>A p.R158= | Silent (SNP) | VAF 154/500 reads (31%) | catalogued as rs537928073, COSV52882215, COSV52883185; called by mutect2, varscan2
- KRT72 | c.1188G>A p.L396= | Silent (SNP) | VAF 158/477 reads (33%) | called by muse, mutect2, varscan2
- LMTK2 | c.618A>G p.E206= | Silent (SNP) | VAF 67/249 reads (27%) | called by muse, mutect2, varscan2
- LRP1B | c.10080C>A p.G3360= | Silent (SNP) | VAF 52/183 reads (28%) | called by muse, mutect2, varscan2
- LTN1 | c.4242G>A p.Q1414= | Silent (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- MCTP2 | c.2446C>T p.L816= | Silent (SNP) | VAF 90/330 reads (27%) | called by muse, mutect2, varscan2
- MYOF | c.4932A>G p.R1644= | Silent (SNP) | VAF 76/230 reads (33%) | called by muse, mutect2, varscan2
- OPLAH | c.258C>T p.N86= | Silent (SNP) | VAF 122/401 reads (30%) | catalogued as rs199637410; called by muse, mutect2, varscan2
- OR5H14 | c.885G>A p.K295= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs201012706, COSV71194428; called by muse, mutect2
- PARD6G | c.531C>T p.G177= | Silent (SNP) | VAF 122/233 reads (52%) | catalogued as rs768101997; called by muse, mutect2, varscan2
- PCDH15 | c.2811G>A p.P937= | Silent (SNP) | VAF 89/339 reads (26%) | catalogued as rs1449039709, COSV57267597; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDH17 | c.1761G>T p.T587= | Silent (SNP) | VAF 159/319 reads (50%) | catalogued as rs770610923, COSV100931914; called by muse, mutect2, varscan2
- PCDHA7 | c.1356C>T p.A452= | Silent (SNP) | VAF 261/741 reads (35%) | catalogued as rs185499663; called by muse, mutect2, varscan2
- PRR14 | c.291G>A p.Q97= | Silent (SNP) | VAF 111/268 reads (41%) | called by muse, mutect2, varscan2
- PTPRD | c.1263G>A p.P421= | Silent (SNP) | VAF 86/198 reads (43%) | catalogued as rs756917717, COSV100645166, COSV61938702; called by muse, mutect2, varscan2
- SELP | c.1848C>T p.C616= | Silent (SNP) | VAF 105/207 reads (51%) | called by muse, mutect2, varscan2
- SGCE | c.750C>A p.P250= (on ENST00000647096; = p.P214= on NM_003919.3) | Silent (SNP) | VAF 89/204 reads (44%) | catalogued as COSV56020627, COSV99721987; called by muse, mutect2, varscan2
- SIRPG | c.180C>A p.P60= | Silent (SNP) | VAF 119/375 reads (32%) | catalogued as COSV53807742; called by muse, mutect2, varscan2
- SLC16A3 | c.243C>T p.C81= | Silent (SNP) | VAF 64/170 reads (38%) | catalogued as rs763366112, COSV101125888, COSV101125904; called by muse, mutect2, varscan2
- SLC35D2 | c.567T>C p.Y189= | Silent (SNP) | VAF 34/133 reads (26%) | called by muse, mutect2, varscan2
- SOGA3 | c.1311G>T p.L437= | Silent (SNP) | VAF 83/231 reads (36%) | called by muse, mutect2, varscan2
- STS | c.267A>G p.A89= | Silent (SNP) | VAF 229/323 reads (71%) | called by muse, mutect2, varscan2
- TEP1 | c.4797C>T p.P1599= | Silent (SNP) | VAF 75/156 reads (48%) | catalogued as rs200043242, COSV52992365, COSV99403008; called by muse, mutect2, varscan2
- TMC3 | c.2385G>A p.P795= | Silent (SNP) | VAF 98/301 reads (33%) | catalogued as rs747725346, COSV63923193; called by muse, mutect2, varscan2
- TMEM132C | c.2724G>T p.L908= | Silent (SNP) | VAF 87/216 reads (40%) | called by muse, mutect2, varscan2
- TMEM184B | c.417C>T p.S139= | Silent (SNP) | VAF 163/315 reads (52%) | called by muse, mutect2, varscan2
- ZBTB48 | c.1959C>A p.S653= | Silent (SNP) | VAF 40/129 reads (31%) | called by muse, mutect2, varscan2
- ZCCHC18 | c.837G>C p.V279= | Silent (SNP) | VAF 74/119 reads (62%) | called by muse, mutect2, varscan2
- ZIC1 | c.414G>A p.A138= | Silent (SNP) | VAF 112/422 reads (27%) | catalogued as rs758167164, COSV51558412; called by muse, mutect2, varscan2
- ZNF407 | c.2358A>G p.K786= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as rs1568134220, COSV99996733; called by muse, mutect2, varscan2
- ZNF835 | c.918C>T p.Y306= | Silent (SNP) | VAF 194/545 reads (36%) | called by muse, mutect2, varscan2
- ZNF845 | c.1992G>A p.R664= | Silent (SNP) | VAF 93/315 reads (30%) | called by muse, mutect2, varscan2
- AGA | c.-47G>C | 5'UTR (SNP) | VAF 143/451 reads (32%) | catalogued as rs200021845; called by muse, mutect2, varscan2
- ARNT | c.138-444T>A | Intron (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2
- CHRND | c.*379C>T | 3'UTR (SNP) | VAF 28/69 reads (41%) | catalogued as rs552885486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CICP28 | chr7:56812197 G>A | 3'Flank (SNP) | VAF 32/182 reads (18%) | catalogued as rs1314874539; called by muse, mutect2, varscan2
- COX20 | c.221+9G>T | Intron (SNP) | VAF 65/297 reads (22%) | called by muse, mutect2, varscan2
- CRADD | c.298+59208G>A | Intron (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- EYS | c.1767-7670T>G | Intron (SNP) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- GLRA2 | c.270+155C>T | Intron (SNP) | VAF 51/74 reads (69%) | called by muse, mutect2, varscan2
- GUSBP4 | n.371G>A | RNA (SNP) | VAF 130/540 reads (24%) | catalogued as rs1385488437; called by muse, mutect2, varscan2
- IER3 | c.211-50C>G | Intron (SNP) | VAF 162/450 reads (36%) | called by muse, mutect2, varscan2
- KDM1A | c.-2A>T | 5'UTR (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- KIF1A | c.1180+536G>A | Intron (SNP) | VAF 20/72 reads (28%) | catalogued as rs1170644759; called by muse, mutect2, varscan2
- KIRREL3 | c.56-118938C>T | Intron (SNP) | VAF 52/77 reads (68%) | catalogued as rs1320257243; called by muse, mutect2, varscan2
- LINC01591 | n.290C>G | RNA (SNP) | VAF 58/366 reads (16%) | called by muse, mutect2, varscan2
- MMP16 | c.1222+5187dup | Intron (INS) | VAF 27/98 reads (28%) | called by mutect2, pindel, varscan2
- MUC19 | n.5695G>C | RNA (SNP) | VAF 54/151 reads (36%) | called by muse, mutect2, varscan2
- NPHP3 | c.670+942G>T | Intron (SNP) | VAF 64/141 reads (45%) | catalogued as rs1251311051; called by muse, mutect2, varscan2
- NRP2 | c.2440+9520_2440+9538del | Intron (DEL) | VAF 134/475 reads (28%) | called by mutect2, pindel, varscan2
- PDE4D | c.456-1270C>T | Intron (SNP) | VAF 69/250 reads (28%) | called by muse, mutect2, varscan2
- PIP5K1A | c.85+11C>T | Intron (SNP) | VAF 221/474 reads (47%) | catalogued as rs1276223714; called by muse, mutect2, varscan2
- SLC25A26 | c.453+41127_453+41129del | Intron (DEL) | VAF 31/92 reads (34%) | catalogued as rs929374034; called by pindel, varscan2
- TPRX1 | c.-91G>A | 5'UTR (SNP) | VAF 38/120 reads (32%) | catalogued as rs945347847; called by mutect2, varscan2
- TTN | c.10303+1120A>G | Intron (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2
- UBE2J1 | c.-21G>A | 5'UTR (SNP) | VAF 39/147 reads (27%) | called by muse, mutect2, varscan2
- USP22 | c.-29C>A | 5'UTR (SNP) | VAF 41/87 reads (47%) | called by muse, mutect2, varscan2
